Somatic mutation profile of tumor specimen 0DFA9B from CCDI case PBBRSA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 5.3 years (1,919 days).
Specimen 0DFA9B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fab715b6-65b2-4f8d-bd82-cea800e5e205.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFA8X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccf3fc72-936c-41e0-ae1b-977d27ac5f7d

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Frame Shift Del 1, 5'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.3218C>T p.T1073M | Missense Mutation (SNP) | VAF 596/1685 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs376079687; called by muse, mutect2, varscan2
- DLG5 | c.5251G>A p.V1751M | Missense Mutation (SNP) | VAF 277/671 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); catalogued as rs369320191; called by muse, mutect2, varscan2
- PTPRS | c.4430G>A p.R1477H | Missense Mutation (SNP) | VAF 219/486 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532712500; called by muse, mutect2, varscan2
- SALL3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1362215791; called by muse, mutect2, varscan2
- DPY19L2 | c.709+2C>T p.X237_splice | Splice Site (SNP) | VAF 329/1073 reads (31%) | called by muse, mutect2, varscan2
- SUSD4 | c.158_168del p.D53Vfs*3 | Frame Shift Del (DEL) | VAF 53/364 reads (15%) | called by mutect2, varscan2
- ADRA1B | c.936C>T p.I312= | Silent (SNP) | VAF 231/621 reads (37%) | catalogued as rs1265592542, COSV60700545; called by muse, mutect2, varscan2
- CDC23 | c.60G>A p.L20= | Silent (SNP) | VAF 84/926 reads (9%) | catalogued as rs1276509620; called by muse, mutect2
- NOL6 | c.3123G>A p.P1041= | Silent (SNP) | VAF 125/592 reads (21%) | catalogued as rs760236765, COSV99955067; called by muse, mutect2, varscan2
- ASB18 | chr2:236264351 C>T | 5'Flank (SNP) | VAF 36/510 reads (7%) | catalogued as rs747462961; called by muse, mutect2
- C8orf33 | c.-16G>T | 5'UTR (SNP) | VAF 153/1098 reads (14%) | catalogued as rs767499143; called by muse, mutect2, varscan2
